Somatic mutation profile of tumor specimen 0DGZFE from CCDI case PBBTRZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.8 years (3,590 days).
Specimen 0DGZFE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96fa0a45-5197-4679-af48-4e75cf3eed63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGYZ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d4a707f-d6ee-4050-8bf1-7e97228de1fa

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Silent 2, Splice Region 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 74/1288 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 32/295 reads (11%) | called by muse, varscan2
- SSH2 | c.1928C>G p.S643* | Nonsense Mutation (SNP) | VAF 48/1230 reads (4%) | called by muse, mutect2
- LRP1 | c.12819G>A p.A4273= | Silent (SNP) | VAF 609/1700 reads (36%) | catalogued as rs754333591; called by muse, mutect2, varscan2
- MED13 | c.1998A>G p.K666= | Silent (SNP) | VAF 46/962 reads (5%) | called by muse, mutect2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 30/438 reads (7%) | catalogued as rs1341369251; called by muse, mutect2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 28/420 reads (7%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
